Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8PY, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8PY-01A (Primary Tumor).

[page 1 of 3]
Collect date:

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Antrum)

“2-Product of gastrectomy

Adenocarcinoma with the following features:

Histologic patterns:

Signet ring cells

Microtubular - Per TSS - 100% tubular.

Histologic grade:

II - Moderately differentiated

Largest tumor size: 2.0 cm

Ulceration: present

Local invasion:

Adjacent fat tissue

Tumor invasion type

Infiltrative

Inflammatory response

Moderate

Tumor implant in perivisceral fat

Absent

Proximal margin

Uninvolved by neoplasia

Distal margin

Uninvolved by neoplasia

Neural invasion

Present

Lymphatic invasion

Present

Blood vessel invasion

Not observed

Lesser omentum

Uninvolved by neoplasia

Lesser curvature lymph nodes

Adenocarcinoma metastasis with capsular perforation: (3/13)

Greater curvature lymph nodes

Adenocarcinoma metastasis with capsular perforation: (8/16)

~~C44~~

ICD-O-3

Adenocarcinoma, tubular 8211/3

with

Adenocarcinoma, tubular 8211/3

signet ring cell
8490/3

Code to highest 8494/3

Site: Gastric antrum C16.3

9/3/7/14

[page 2 of 3]
Small intestine mesentery lymph node
Uninvolved by neoplasia: (0/1)

Chain 12a lymph nodes
Uninvolved by neoplasia: (0/2)

Hepatic artery/celiac trunk lymph nodes:
Adenocarcinoma metastasis with capsular perforation: (1/8)

12p lymph nodes:
Uninvolved by neoplasia: (0/3)

Gallbladder:
Chronic cholecystitis"

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____
Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Signet Ring Cells, Microtubular Adenocarcinoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	100% Tubular (intestinal type)	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Case was reviewed based on top slide to be sent to BCR	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Per TSS, dx discrepancy
form states TCGA
tumor to be adenocarcinoma,
tubular. BCR

Criteria	has 12/11/13	Yes	No
Diagnosis Discrepancy	100% Tubular	☒	☐
RNA Discrepancy		☒	☐

Source: NCI Genomic Data Commons file eb6b5f7c-f042-4680-a441-04ff6dda5128 (TCGA-VQ-A8PY.AC98411B-C7BF-40A8-AE98-BF35A9C0D4D2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).